Somatic mutation profile of tumor specimen TCGA-AG-3999-01A (aliquot TCGA-AG-3999-01A-01W-1073-09) from TCGA case TCGA-AG-3999, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 61.1 years (22,311 days).
Specimen TCGA-AG-3999-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e8c4eec-7506-4c7c-b0aa-6f5db5f66d55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3999-10A (Blood Derived Normal), aliquot TCGA-AG-3999-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/605d227d-e581-49a6-96b1-56cb6c709b14

The open-access MAF lists 102 somatic variants for this specimen: 77 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 23, Nonsense Mutation 5, Frame Shift Ins 3, Frame Shift Del 2, Splice Site 2, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 171/201 reads (85%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 109/145 reads (75%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.1565A>G p.Q522R (on ENST00000272895 / NM_173076.3; = p.Q204R on NM_015657.3) | Missense Mutation (SNP) | VAF 55/260 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as COSV55959860; called by muse, mutect2, varscan2
- ADAM29 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 85/227 reads (37%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.602); catalogued as rs767242480, COSV63663770; called by muse, mutect2, varscan2
- AHNAK2 | c.11610A>C p.K3870N | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as COSV60915788; called by muse, mutect2, varscan2
- AKAP4 | c.886G>T p.G296C | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV62074488; called by muse, mutect2, varscan2
- APC | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 39/47 reads (83%) | catalogued as CM990148, COSV57345794; called by muse, mutect2, varscan2
- ATP6V1G3 | c.327A>T p.E109D | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV55278507, COSV55279224; called by muse, mutect2, varscan2
- BCL9L | c.3121C>T p.Q1041* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as rs1338705863, COSV52684577; called by muse, mutect2, varscan2
- C2CD3 | c.1907G>A p.W636* | Nonsense Mutation (SNP) | VAF 72/293 reads (25%) | catalogued as COSV100486248, COSV58093258; called by muse, mutect2, varscan2
- C3orf20 | c.561G>A p.M187I | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.052); catalogued as COSV53785577; called by muse, mutect2, varscan2
- CACNA1F | c.665G>T p.S222I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59904573; called by muse, mutect2
- CACTIN | c.1823G>A p.R608Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.07); catalogued as rs371228649; called by muse, mutect2
- CC2D2A | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 68/223 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV67503721; called by muse, mutect2, varscan2
- CNOT3 | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 72/186 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201217351, COSV55362332, COSV99651517; called by mutect2, varscan2
- COL12A1 | c.8946G>T p.L2982F | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.632); catalogued as COSV59396386; called by muse, mutect2, varscan2
- CRTC2 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 361/751 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57843003; called by muse, mutect2, varscan2
- CSF2RA | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 141/232 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs777638014, COSV62623722; called by muse, mutect2, varscan2
- DDX21 | c.884G>T p.G295V | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62555746; called by muse, mutect2, varscan2
- DISP2 | c.4063G>A p.A1355T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs146679685; called by muse, mutect2, varscan2
- EHMT2 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1405497274, COSV64996117; called by muse, mutect2, varscan2
- ERICH5 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 339/443 reads (77%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs762941709, COSV59315425; called by muse, mutect2, varscan2
- GRIA3 | c.2167G>A p.A723T | Missense Mutation (SNP) | VAF 116/311 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.279); catalogued as COSV52060487; called by muse, mutect2, varscan2
- HOXD8 | c.824_825insC p.K275Nfs*66 | Frame Shift Ins (INS) | VAF 18/182 reads (10%) | catalogued as COSV57485520; called by mutect2, pindel
- HSD17B3 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 81/297 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.345); catalogued as rs568096279, COSV64556292; called by muse, mutect2, varscan2
- IGSF11 | c.703+1G>A p.X235_splice (on ENST00000393775 / NM_001015887.3; = p.X234_splice on NM_152538.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 166/277 reads (60%) | catalogued as rs1468676629, COSV61170157; called by muse, mutect2, varscan2
- ISLR | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs149796219, COSV51434720; called by muse, mutect2, varscan2
- JAKMIP1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs775238240, COSV51531038; called by muse, varscan2
- KCNS2 | c.1114A>G p.M372V | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54638609; called by muse, mutect2, varscan2
- KIAA0100 | c.1708T>A p.L570I | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.642); catalogued as COSV66492948; called by muse, mutect2, varscan2
- MEIS3 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs563242031, COSV58983604; called by muse, mutect2, varscan2
- MGA | c.7304G>A p.R2435Q (on ENST00000219905 / NM_001164273.1; = p.R2226Q on NM_001080541.2) | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54951059, COSV54964414; called by muse, mutect2, varscan2
- MYLK3 | c.1933G>A p.V645I | Missense Mutation (SNP) | VAF 85/150 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.391); catalogued as rs763522795, COSV67363940; called by muse, mutect2, varscan2
- NOL4 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 78/124 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs755854498, COSV52347295; called by muse, mutect2, varscan2
- NPC1L1 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs201421514, COSV56925327; called by muse, mutect2, varscan2
- NUGGC | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs199622602; called by muse, mutect2, varscan2
- OR8J1 | c.235C>G p.P79A | Missense Mutation (SNP) | VAF 16/343 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV57318306; called by muse, mutect2
- PALM2AKAP2 | c.790A>C p.K264Q (on ENST00000259318 / NM_001136562.3; = p.K495Q on NM_007203.5) | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV52176519; called by muse, mutect2, varscan2
- PCLO | c.6697C>T p.P2233S | Missense Mutation (SNP) | VAF 57/285 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.755); catalogued as rs868607982, COSV61636251; called by muse, mutect2, varscan2
- PCLO | c.6600T>G p.I2200M | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); catalogued as rs747188300, COSV61636261; called by muse, mutect2, varscan2
- PCNA | c.506T>G p.F169C | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52532226; called by muse, mutect2, varscan2
- PI4KA | c.2607C>G p.I869M | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV55411434; called by muse, varscan2
- PLEKHA2 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV66242723; called by muse, mutect2, varscan2
- PNLIP | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 106/275 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs142749694; called by muse, mutect2, varscan2
- POPDC3 | c.866G>A p.C289Y | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV54644215; called by muse, mutect2, varscan2
- PPFIA4 | c.2884C>T p.R962C (on ENST00000447715; = p.R963C on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs761375177, COSV55315271; called by muse, mutect2, varscan2
- PTPRT | c.3953G>A p.R1318H | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1441976520, COSV61982213, COSV61999431; called by muse, mutect2, varscan2
- PTPRU | c.3890G>A p.R1297Q | Missense Mutation (SNP) | VAF 35/39 reads (90%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as rs373365649; called by muse, mutect2, varscan2
- RALGAPA1 | c.1612A>G p.I538V | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1228538571, COSV51883482; called by muse, mutect2, varscan2
- RBM10 | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 83/164 reads (51%) | catalogued as COSV61309256, COSV61309471; called by muse, mutect2, varscan2
- RGS13 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1441202055, COSV67346066; called by muse, mutect2, varscan2
- RHOA | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.56); catalogued as COSV69042505; called by muse, mutect2
- SAT2 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as rs777816800, COSV52646910; called by muse, mutect2, varscan2
- SEMA6D | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as COSV60380324; called by muse, mutect2
- SYTL5 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs753440296, COSV52901297; called by muse, varscan2
- TDRKH | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 141/280 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1004423330, COSV64316048; called by muse, mutect2, varscan2
- TF | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV53920495; called by mutect2, varscan2
- TMTC1 | c.1156G>A p.G386S (on ENST00000539277 / NM_001193451.2; = p.G278S on NM_175861.3) | Missense Mutation (SNP) | VAF 87/137 reads (64%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as rs910785203, COSV55477210; called by muse, mutect2, varscan2
- TRIM41 | c.557G>A p.C186Y | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59319096, COSV59319187; called by muse, mutect2, varscan2
- TRPA1 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV51562164, COSV51573801; called by muse, mutect2, varscan2
- TRPC6 | c.2707T>C p.S903P | Missense Mutation (SNP) | VAF 151/259 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV60254989; called by muse, mutect2, varscan2
- TTR | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.495); catalogued as rs148538950; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBL3 | c.65_66del p.K22Rfs*7 | Frame Shift Del (DEL) | VAF 25/171 reads (15%) | catalogued as rs750432475; called by mutect2, pindel, varscan2
- UBR5 | c.4912G>A p.G1638R | Missense Mutation (SNP) | VAF 229/301 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55287658; called by muse, mutect2, varscan2
- ZDHHC8 | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57710383; called by muse, mutect2
- ZFHX4 | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757130756, COSV50830274; called by muse, mutect2, varscan2
- ZNF208 | c.2828A>C p.K943T | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV68100536; called by muse, mutect2, varscan2
- ZNF554 | c.1246T>G p.S416A | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.044); catalogued as COSV57885673; called by muse, varscan2
- ZNF761 | c.632G>A p.R211K | Missense Mutation (SNP) | VAF 12/387 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.177); catalogued as COSV100483468; called by muse, mutect2
- ADGRF4 | c.1010A>C p.E337A | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- CGB5 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- F8 | c.6116-3_6116-2del p.X2039_splice | Splice Site (DEL) | VAF 133/454 reads (29%) | called by mutect2, pindel, varscan2
- KCNB2 | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 11/282 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PRKDC | c.3346_3350dup p.D1117Efs*7 | Frame Shift Ins (INS) | VAF 14/83 reads (17%) | called by mutect2, pindel, varscan2
- SLC6A11 | c.1515del p.Y506Tfs*12 | Frame Shift Del (DEL) | VAF 19/132 reads (14%) | called by mutect2, pindel, varscan2
- TRAV6 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 5/114 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); called by muse, mutect2
- ZNF142 | c.907_908dup p.P304Nfs*21 (on ENST00000411696 / NM_001379660.1; = p.P104Nfs*21 on NM_001105537.4 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 153/409 reads (37%) | called by mutect2, varscan2
- ACACB | c.3261C>T p.I1087= | Silent (SNP) | VAF 8/165 reads (5%) | called by muse, mutect2
- ASCL4 | c.48G>A p.S16= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV60816687; called by muse, mutect2, varscan2
- BAG1 | c.243C>T p.T81= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV56302989; called by muse, mutect2
- BSN | c.3315G>A p.P1105= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as rs1349292792, COSV56518225; called by muse, mutect2, varscan2
- CYP4F3 | c.1470C>T p.R490= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs144943990; called by muse, mutect2, varscan2
- DELE1 | c.285C>T p.A95= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as rs1380672269; called by muse, mutect2
- DOCK3 | c.3720C>T p.Y1240= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as rs1354109421; called by muse, mutect2
- FRMPD3 | c.2109C>T p.P703= | Silent (SNP) | VAF 44/81 reads (54%) | called by muse, mutect2, varscan2
- HEATR1 | c.4755C>T p.Y1585= | Silent (SNP) | VAF 201/242 reads (83%) | catalogued as rs757455326, COSV63981208; called by muse, varscan2
- KCNG4 | c.417C>T p.C139= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as rs766598106, COSV57583882; called by muse, mutect2, varscan2
- NEMF | c.1701T>G p.A567= | Silent (SNP) | VAF 88/154 reads (57%) | catalogued as COSV53591709; called by muse, mutect2, varscan2
- NTNG2 | c.504C>T p.A168= | Silent (SNP) | VAF 19/27 reads (70%) | catalogued as rs781430143, COSV62366774; called by muse, mutect2, varscan2
- NUP205 | c.3381C>T p.T1127= | Silent (SNP) | VAF 81/183 reads (44%) | catalogued as rs367706530, COSV53659473; called by muse, mutect2, varscan2
- OR11H12 | c.756C>T p.A252= | Silent (SNP) | VAF 82/582 reads (14%) | catalogued as rs1278564939; called by muse, varscan2
- OR5AS1 | c.312C>T p.F104= | Silent (SNP) | VAF 37/174 reads (21%) | catalogued as rs142110904; called by muse, mutect2
- PI4KA | c.2469C>T p.V823= | Silent (SNP) | VAF 130/264 reads (49%) | catalogued as COSV55411452; called by muse, mutect2, varscan2
- PKLR | c.1335G>A p.A445= | Silent (SNP) | VAF 53/331 reads (16%) | catalogued as rs771876200, COSV61361238; called by muse, mutect2, varscan2
- PRKD2 | c.1377G>A p.P459= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs61739905; called by muse, mutect2, varscan2
- PUS10 | c.636G>A p.V212= | Silent (SNP) | VAF 56/171 reads (33%) | catalogued as COSV57452517; called by muse, mutect2, varscan2
- SHFL | c.805C>T p.L269= | Silent (SNP) | VAF 59/104 reads (57%) | catalogued as COSV53462391; called by muse, mutect2, varscan2
- SLC25A14 | c.951C>T p.Y317= | Silent (SNP) | VAF 293/655 reads (45%) | catalogued as rs1472208939, COSV54418228; called by muse, mutect2, varscan2
- SORCS3 | c.1968C>T p.D656= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs372850065; called by muse, mutect2, varscan2
- ZFP30 | c.828G>T p.G276= | Silent (SNP) | VAF 10/242 reads (4%) | catalogued as COSV63622645; called by muse, mutect2
- AL136982.4 | n.1729G>A | RNA (SNP) | VAF 71/154 reads (46%) | catalogued as rs15718; called by muse, mutect2, varscan2
- CPLANE1 | chr5:37168844 T>C | 3'Flank (SNP) | VAF 8/159 reads (5%) | called by muse, mutect2
